CCDI case PBCKKY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/60f04647-b0f4-4e59-bb50-fb4a23704b7a

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.8 years (5,047 days).

Biospecimens (3 samples)
- Sample 0DU3KK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3LI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
